Somatic mutation profile of tumor specimen TARGET-10-PAREWE-09A (aliquot TARGET-10-PAREWE-09A-01D) from TARGET case TARGET-10-PAREWE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,106 days).
Specimen TARGET-10-PAREWE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ef5e3f2-dd16-4287-999e-b2d7a30202d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREWE-10A (Blood Derived Normal), aliquot TARGET-10-PAREWE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/121f903f-9800-4930-aaa4-a496289ff15a

The open-access MAF lists 63 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Intron 4, 5'Flank 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L12 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs763532112, COSV55863967; called by mutect2, varscan2
- CCND2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs777751484, COSV54224677; called by muse, mutect2, varscan2
- DENND2C | c.2677G>C p.E893Q (on ENST00000393274 / NM_001256404.2; = p.E836Q on NM_198459.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1052366700; called by muse, mutect2, varscan2
- DNAJC13 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99607469; called by muse, varscan2
- DOCK1 | c.2299G>C p.D767H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as rs1367250635; called by muse, mutect2
- EGFR | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369399038, COSV51779590, COSV51859123; called by mutect2, varscan2
- GNB1 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1231842600, COSV101060718, COSV66101380; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LMTK2 | c.3631A>G p.S1211G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as rs1225326134; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA6 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV65357529; called by muse, mutect2, varscan2
- PTX3 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as COSV55821673; called by muse, mutect2, varscan2
- RBP1 | c.45G>C p.E15D (on ENST00000619087 / NM_001365940.2; = p.E77D on NM_002899.5) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99218585, COSV99218965; called by muse, mutect2, varscan2
- RICTOR | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.157); catalogued as rs1200274304; called by muse, mutect2
- SLC13A5 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV53425161, COSV99545622; called by muse, mutect2, varscan2
- TBX15 | c.994G>A p.E332K (on ENST00000369429 / NM_001330677.2; = p.E226K on NM_152380.3) | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.915); catalogued as rs1225498534, COSV52869563; called by muse, mutect2, varscan2
- TBX22 | c.633C>T p.H211= | Splice Region (SNP) | VAF 12/37 reads (32%) | catalogued as rs376259951; called by muse, mutect2, varscan2
- TOPBP1 | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99604734; called by muse, mutect2, varscan2
- TRIM25 | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100380904; called by muse, mutect2, varscan2
- TSEN34 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.914); catalogued as COSV55477573; called by muse, mutect2, varscan2
- XPNPEP1 | c.128G>C p.R43T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.038); catalogued as COSV100450958; called by muse, mutect2, varscan2
- AC005833.1 | c.1673T>C p.V558A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- AMY1A | c.995A>C p.D332A | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- BIRC6 | c.13036C>T p.H4346Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.095); called by muse, varscan2
- CCDC180 | c.1516C>A p.H506N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.037); called by muse, mutect2
- DAPL1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2
- EFCAB7 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); called by muse, mutect2
- ESR1 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LYVE1 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MAP2K5 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MMP1 | c.1169A>T p.Y390F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- MTMR7 | c.90G>C p.L30F | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- PCNX4 | c.3365C>T p.S1122L (on ENST00000406854 / NM_001330177.2; = p.S888L on NM_022495.5) | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PGBD4 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PPFIA2 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRPF40A | c.2694G>T p.E898D | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.969); called by muse, mutect2
- RAB23 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB37 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- RBM45 | c.1120G>C p.D374H (on ENST00000616198 / NM_001365579.1; = p.D372H on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRGAP1 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- SYT4 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2
- TIMM10B | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.37120G>A p.E12374K (on ENST00000591111; = p.E4950K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | PolyPhen benign (0.254); called by muse, mutect2, varscan2
- UBA2 | c.317T>C p.F106S | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTP20 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, varscan2
- WDR44 | c.2228G>A p.R743K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ABT1 | c.660G>C p.L220= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- CCNO | c.795G>T p.V265= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- GALNT15 | c.1710G>A p.V570= | Silent (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- INTS4 | c.2619G>A p.Q873= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- PDE11A | c.1701G>A p.V567= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- SETX | c.5187C>T p.I1729= | Silent (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- SLC22A3 | c.324C>T p.L108= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs766552536; called by muse, varscan2
- ULK2 | c.1245G>A p.Q415= | Silent (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- URGCP | c.780G>A p.A260= (on ENST00000453200 / NM_001077663.3; = p.A251= on NM_017920.4) | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs1337170901, COSV56253078; called by muse, mutect2
- UTP23 | c.294G>C p.V98= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as COSV52665922; called by muse, mutect2
- ZC3H13 | c.1581G>C p.R527= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- CACNA1E | c.5268-1972G>A | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs1460522827; called by muse, mutect2
- FOXP2 | c.*3403G>C | 3'UTR (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2
- NT5DC3 | chr12:103841505 G>T | 5'Flank (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2
- SCN3A | c.3967-42C>G | Intron (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.236+8569G>C | Intron (SNP) | VAF 14/77 reads (18%) | called by muse, varscan2
- TIMM10B | c.39+24G>C | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, varscan2
- TRIM73 | chr7:75394321 G>A | 5'Flank (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
